Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A3M1, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A3M1-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

[Redacted Patient Information]

Date of Receipt:

Physician:

Date of Report:

CC:

Patient Address: [Redacted Patient Address]

....

Clinical Diagnosis & History:

Retroperitoneal sarcoma.

Specimens Submitted:

- 1: Left retroperitoneal liposarcoma
- 2: Questionable liposarcoma sigmoid colon

DIAGNOSIS:

1. Left retroperitoneum, resection:

- High grade dedifferentiated liposarcoma.
- Tumor size: 17x12 x 6.0 cm.
- The dedifferentiated component predominates and shows a high grade malignant fibrous histiocytoma-like morphology.
- Focal well-differentiated liposarcoma component is also present.
- The tumor has extensive areas of necrosis (40%).
- The tumor is grossly surrounded by a smooth, intact membrane, which represents the surgical margin.

2. Sigmoid colon; excision:

- Well-differentiated liposarcoma, lipoma-like (4 .0 x 3.5 x 2.0 cm).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh labeled, "left retroperitoneal sarcoma", and consist of an unoriented lobulated mass of adipose tissue measuring 17x 12 x 6.0 cm. The entire specimen is inked and serially sectioned to reveal firm tan necrotic lobulated mass surrounded by adipose tissue. Grossly necrosis is estimated approximately 40%. The tumor appears surrounded by an intact thin membrane. Representative sections are submitted.

Summary of sections:

** Continued on next page **

ICD-0-3
dedifferentiated liposarcoma 8858/3
Site: retroperitoneum C48.0
hw 12/23/11

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

Accession #: [REDACTED]

Date of Report: [REDACTED]

Page 2 of 2

T- tumor

TN- tumor with necrosis

2. The specimen is received fresh labeled, "Questionable liposarcoma, sigmoid colon", and consist of an unoriented lobulated mass of adipose tissue measuring 4x3.5 x2 cm. The entire specimen is inked and serially sectioned to reveal firm slightly firm adipose tissue. No necrosis is identified.

Summary of sections:

u-undesignated

Summary of Sections:

Part 1: Left retroperitoneal liposarcoma

Block	Sect.	Site	PCs
6	t		6
4	tn		4

Part 2: Questionable liposarcoma sigmoid colon

Block	Sect.	Site	PCs
4	u		4

** End of Report **

Source: NCI Genomic Data Commons file 876b09ce-961b-463a-b8d6-8b0b0ca6d53f (TCGA-DX-A3M1.1AC22456-A8B4-4DED-9B69-66B8E77ED918.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).